TCGA case TCGA-RN-A68Q — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nerve Sheath Tumors; Primary site: Meninges; Tissue source site: St. Joseph's Hospital AZ. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d51b9939-aef7-426b-a57f-01c3684e2dc2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Malignant peripheral nerve sheath tumor: ICD-O-3 morphology code: 9540/3; ICD-10 code: C70.1; Tissue or organ of origin: Spinal meninges; Site of resection or biopsy: Spinal meninges; Classification of tumor: primary; Age at diagnosis: 62.9 years (22,981 days); Year of diagnosis: 2010; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.4; Tumor length measurement: 1.5; Tumor width measurement: 0.7.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.5; Tumor length measurement: 1.5; Tumor width measurement: 1.4.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 2; Tumor width measurement: 3.
   Pathology details: Consistent pathology review: Yes; Necrosis percent: 5; Necrosis present: Yes.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.1; Tumor length measurement: 0.5; Tumor width measurement: 0.3.

Follow-up (1 entry)
- Days to follow up: 22 days; Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RN-A68Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-RN-A68Q-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-RN-A68Q-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RN-A68Q-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Malignant Peripheral Nerve Sheath Tumors (MPNST); Site of primary tumor other: Lumbar; Tumor total necrosis: <10% (focal necrosis).
- Primary pathology, Tumor tissue sites: Submitted tumor site: Head and Neck - Other (please specify.
- Primary pathology, Tumor sizes, Tumor size 1: Lesion radiologic length: 2; Lesion radiologic width: 3.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 22 days; disease-specific survival: no event (censored), 22 days; progression-free interval: no event (censored), 22 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RN-A68Q-01A-11D-A306-01): tumor purity 1, ploidy 2, whole-genome doublings 0.
